Somatic mutation profile of tumor specimen MP2PRT-PAWBKL-TMP1-A (aliquot MP2PRT-PAWBKL-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAWBKL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,014 days).
Specimen MP2PRT-PAWBKL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd939cd2-78fc-43ef-b160-20f766f0b288.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBKL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBKL-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20c1a46d-4b0f-427d-8d15-c0ddbbd7a0fe

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJM1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs1337852010; called by muse, mutect2, varscan2
- CDH15 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 91/488 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016544957, COSV57028103; called by muse, varscan2
- PAX5 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63908550, COSV63912885; called by muse, mutect2, varscan2
- GEN1 | c.1062A>T p.L354F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2
- UBE2E3 | c.95dup p.E33* | Frame Shift Ins (INS) | VAF 72/414 reads (17%) | called by mutect2, pindel, varscan2
- SLC38A11 | c.465C>T p.D155= (on ENST00000409149 / NM_001351539.1; = p.D133= on NM_173512.2) | Silent (SNP) | VAF 58/234 reads (25%) | catalogued as rs369753536, COSV58051944; called by muse, mutect2, varscan2
